Somatic mutation profile of tumor specimen TCGA-CD-A48A-01A (aliquot TCGA-CD-A48A-01A-12D-A24D-08) from TCGA case TCGA-CD-A48A, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.1 years (20,839 days).
Specimen TCGA-CD-A48A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d54de73-0670-4c92-9939-2d5f53c5a8c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A48A-10A (Blood Derived Normal), aliquot TCGA-CD-A48A-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4848648f-0336-41c3-a489-92dedbea71f8

The open-access MAF lists 244 somatic variants for this specimen: 186 protein-altering or splice-affecting, 48 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 48, RNA 4, Intron 4, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 1, Splice Region 1, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGI2 | c.1808T>G p.L603R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, mutect2, varscan2
- ABHD12B | c.505T>G p.F169V (on ENST00000337334 / NM_001206673.2; = p.F92V on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV61569540; called by muse, mutect2, varscan2
- ACCSL | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66581373; called by muse, mutect2, varscan2
- ADAMTS16 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV56991774; called by muse, mutect2
- ADAMTSL3 | c.4820A>C p.K1607T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.63); PolyPhen benign (0.024); catalogued as COSV54450406; called by muse, mutect2, varscan2
- AL592490.1 | c.2509G>T p.V837F | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV69426506; called by muse, mutect2, varscan2
- ALDH6A1 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63246484; called by muse, mutect2, varscan2
- ALPK3 | c.514A>T p.M172L | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV51934121; called by muse, mutect2, varscan2
- AMIGO2 | c.1037del p.G346Efs*5 | Frame Shift Del (DEL) | VAF 27/258 reads (10%) | catalogued as COSV99873508; called by mutect2, pindel, varscan2
- ANOS1 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.28); catalogued as rs1202486562, COSV52920672; called by muse, mutect2, varscan2
- AOAH | c.1060T>C p.L354= | Splice Region (SNP) | VAF 28/111 reads (25%) | catalogued as COSV51742270; called by muse, mutect2, varscan2
- ARHGAP20 | c.2567A>T p.K856M | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV52812261, COSV52812439; called by muse, mutect2, varscan2
- ARHGEF1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61527917; called by muse, mutect2, varscan2
- ARMCX1 | c.574T>G p.F192V | Missense Mutation (SNP) | VAF 81/108 reads (75%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.535); catalogued as COSV65705234; called by muse, mutect2, varscan2
- ARMH3 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as rs377517671; called by muse, mutect2, varscan2
- ATP12A | c.2446C>A p.P816T | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54517206; called by muse, mutect2, varscan2
- BCO1 | c.1576A>C p.K526Q | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV50729888; called by muse, mutect2, varscan2
- BHLHE23 | c.367C>A p.L123M (on ENST00000370346; = p.L139M on NM_080606.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64846462; called by muse, mutect2
- BLM | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61924462; called by muse, mutect2, varscan2
- BMP2 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66578143; called by muse, mutect2, varscan2
- C11orf16 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV58167475; called by muse, mutect2, varscan2
- C3orf70 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.194); catalogued as COSV58587530, COSV58588063; called by muse, mutect2, varscan2
- C6orf58 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1444125732, COSV61666607; called by muse, mutect2, varscan2
- CACNA2D3 | c.2729A>C p.N910T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV55543883; called by muse, mutect2, varscan2
- CAMK4 | c.357A>C p.E119D | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV56672173; called by muse, mutect2, varscan2
- CARF | c.1481T>A p.I494N | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.214); catalogued as COSV57547841; called by muse, mutect2, varscan2
- CCDC125 | c.1421G>C p.S474T | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.059); catalogued as COSV67288156; called by muse, mutect2, varscan2
- CCNB3 | c.847T>G p.L283V | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV52074353; called by muse, mutect2, varscan2
- CD1A | c.223T>G p.F75V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56860556, COSV99192377; called by muse, mutect2, varscan2
- CEP20 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV55384371; called by muse, mutect2, varscan2
- CHD9 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV68298398; called by muse, mutect2, varscan2
- CHST8 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52857352; called by muse, mutect2, varscan2
- CNGA3 | c.1969A>C p.K657Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55624743; called by muse, mutect2, varscan2
- CNTN1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 107/184 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs4408370, COSV61639330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN5 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.859); catalogued as COSV54315647; called by muse, mutect2, varscan2
- COL24A1 | c.1148G>C p.R383T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65307267; called by muse, mutect2, varscan2
- CREB3L3 | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV50203980; called by muse, mutect2, varscan2
- DCLK1 | c.785A>C p.K262T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55189332; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DKK1 | c.759A>T p.Q253H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV64760316; called by muse, mutect2, varscan2
- DMP1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as COSV56820256; called by muse, mutect2, varscan2
- DNAH9 | c.8582A>G p.K2861R | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.572); catalogued as COSV52352428; called by muse, mutect2, varscan2
- DOCK4 | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV70321293; called by muse, mutect2, varscan2
- DZIP1 | c.1492T>C p.S498P (on ENST00000347108; = p.S479P on NM_014934.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.593); catalogued as COSV61266161; called by muse, mutect2, varscan2
- EFHB | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV55548813; called by muse, mutect2
- ELMO1 | c.469T>C p.F157L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.048); catalogued as COSV60306305; called by muse, mutect2, varscan2
- EPAS1 | c.2001G>T p.L667F | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.129); catalogued as COSV55386976; called by muse, mutect2, varscan2
- EPHA3 | c.2497-2A>T p.X833_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as COSV60708331; called by muse, mutect2, varscan2
- EPHB2 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs369350136; called by muse, mutect2, varscan2
- ERBB4 | c.3187C>A p.Q1063K | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.93); catalogued as COSV61483996, COSV61491924; called by muse, mutect2
- ERICH3 | c.1377A>C p.Q459H | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as COSV58608185; called by muse, mutect2, varscan2
- EXOC3L1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1046349778, COSV58874899; called by muse, mutect2, varscan2
- FAM111A | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV64655404; called by muse, mutect2, varscan2
- FAM170A | c.172T>C p.C58R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58925437; called by muse, mutect2, varscan2
- FAM220A | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV57626471; called by muse, mutect2, varscan2
- FLNC | c.7328G>A p.R2443Q | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.166); catalogued as rs370293647; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM1 | c.4154T>G p.I1385S | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66524488; called by muse, mutect2, varscan2
- GABRB1 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 85/116 reads (73%) | SIFT tolerated (0.33); PolyPhen benign (0.32); catalogued as COSV54983657; called by muse, mutect2, varscan2
- GLB1L | c.1768A>G p.R590G | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV55476862; called by muse, mutect2, varscan2
- GMPPB | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV57537452; called by muse, mutect2, varscan2
- GPR132 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs377690495, COSV61677977; called by muse, mutect2, varscan2
- GPS1 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV57649315; called by muse, mutect2, varscan2
- GPX6 | c.161T>C p.I54T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs374992726, COSV62657209; called by muse, mutect2, varscan2
- H1-2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759161097, COSV59190965; called by muse, mutect2, varscan2
- H1-3 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1054213579, COSV55097524; called by muse, mutect2, varscan2
- HEATR3 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 115/148 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53529527; called by muse, mutect2, varscan2
- HEATR5A | c.1496A>G p.K499R | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV66341447; called by muse, mutect2, varscan2
- HLA-DPA1 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV70089168; called by muse, mutect2, varscan2
- HSD11B1 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1558201263, COSV54827720; called by muse, mutect2, varscan2
- HTR3B | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52744993; called by muse, mutect2, varscan2
- HTR6 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as rs201820273, COSV53873172; called by muse, mutect2, varscan2
- HYDIN | c.6601G>A p.E2201K | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs200310909, COSV59251399; called by muse, mutect2, varscan2
- IL31RA | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs565501186, COSV51680542; called by muse, mutect2, varscan2
- ITGAE | c.886A>C p.S296R | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV53994835; called by muse, mutect2, varscan2
- JSRP1 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 76/87 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV55559258; called by muse, mutect2, varscan2
- KCNA4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs775798928, COSV60250783; called by muse, mutect2, varscan2
- KCNC3 | c.892T>C p.F298L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV65387666; called by muse, mutect2, varscan2
- KCNH5 | c.2155C>A p.L719M | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59761861; called by muse, mutect2, varscan2
- KIAA1614 | c.3068A>T p.K1023M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62550972; called by muse, mutect2, varscan2
- LAMA2 | c.387T>A p.D129E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70348523; called by muse, mutect2, varscan2
- LCN2 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV52980943; called by muse, mutect2
- LDLRAD4 | c.424A>T p.T142S | Missense Mutation (SNP) | VAF 94/105 reads (90%) | SIFT tolerated (0.53); PolyPhen benign (0.08); catalogued as COSV63337964; called by muse, mutect2, varscan2
- LEFTY1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146082781; called by muse, mutect2, varscan2
- LIMK1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1554699364, COSV60281918; called by muse, mutect2, varscan2
- LMO7 | c.3239A>G p.K1080R (on ENST00000357063; = p.K761R on NM_005358.5) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.238); catalogued as rs761122156, COSV58538039; called by muse, mutect2, varscan2
- LRRC3 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as rs142928276; called by mutect2, varscan2
- LRRC37A3 | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs756384249, COSV58534839; called by muse, mutect2, varscan2
- MAGEA6 | c.656A>G p.E219G | Missense Mutation (SNP) | VAF 83/110 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV61449041; called by muse, mutect2, varscan2
- MBTPS1 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58570981; called by muse, mutect2, varscan2
- MIOX | c.155C>G p.T52R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53313186; called by muse, mutect2, varscan2
- MPDZ | c.4495G>A p.E1499K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1204108685, COSV59918648; called by muse, mutect2, varscan2
- MTMR6 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as rs750462481, COSV67808481; called by muse, mutect2, varscan2
- MUC16 | c.14712G>T p.Q4904H | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV67469674; called by muse, mutect2
- MUC17 | c.8898T>G p.S2966R | Missense Mutation (SNP) | VAF 282/512 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV60290132; called by muse, mutect2, varscan2
- MUC17 | c.10979T>G p.V3660G | Missense Mutation (SNP) | VAF 141/254 reads (56%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV60290137; called by muse, mutect2, varscan2
- MYH3 | c.803T>G p.L268R | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56865639; called by muse, mutect2, varscan2
- MYH8 | c.3598G>A p.A1200T | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV67965573; called by muse, mutect2, varscan2
- NCKAP5 | c.3816A>C p.K1272N | Missense Mutation (SNP) | VAF 65/88 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58425529; called by muse, mutect2, varscan2
- NCKIPSD | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1403785323, COSV53661292; called by muse, mutect2, varscan2
- NEMP1 | c.1066C>T p.R356* (on ENST00000300128 / NM_001130963.2; = p.R283* on NM_015257.3) | Nonsense Mutation (SNP) | VAF 103/185 reads (56%) | catalogued as rs771521892, COSV55662758; called by muse, mutect2, varscan2
- OR10K1 | c.506A>T p.H169L | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs747527834, COSV56872227; called by muse, mutect2, varscan2
- OR13C4 | c.932T>C p.L311P | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV52926849; called by muse, mutect2, varscan2
- OR2T4 | c.689T>A p.F230Y | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV63544127; called by muse, mutect2, varscan2
- OR2T8 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178081; called by muse, mutect2, varscan2
- OR4A16 | c.129T>G p.I43M | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1393493678, COSV59043367; called by muse, mutect2, varscan2
- OR4C15 | c.379T>A p.S127T (on ENST00000314644; = p.S73T on NM_001001920.2) | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.329); catalogued as rs1365786004, COSV58951546, COSV58952166; called by muse, mutect2, varscan2
- OR51D1 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.631); catalogued as rs370692155, COSV62914000; called by muse, mutect2, varscan2
- OR5AC2 | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62279589; called by muse, mutect2, varscan2
- OR6F1 | c.133A>T p.I45F | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57468035; called by muse, mutect2, varscan2
- OR6N2 | c.194T>G p.V65G | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV59411665; called by muse, mutect2, varscan2
- PACS1 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57697928; called by muse, mutect2, varscan2
- PAK3 | c.1604A>T p.K535I (on ENST00000262836 / NM_001324328.2; = p.K520I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV53275039; called by muse, mutect2, varscan2
- PARP9 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64450767, COSV64451444; called by muse, mutect2, varscan2
- PCARE | c.2015A>G p.K672R | Missense Mutation (SNP) | VAF 86/116 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV59055189; called by muse, mutect2, varscan2
- PCBP1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV57850540; called by muse, mutect2, varscan2
- PCDH10 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1334229279, COSV52095425, COSV99994221; called by muse, mutect2, varscan2
- PCDHA1 | c.2314T>G p.F772V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV65374660; called by muse, mutect2, varscan2
- PCDHB10 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.217); catalogued as COSV99503715; called by muse, mutect2
- PCDHGA9 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.298); catalogued as COSV53917968; called by muse, mutect2, varscan2
- PCNX4 | c.905C>A p.A302D (on ENST00000406854 / NM_001330177.2; = p.A68D on NM_022495.5) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.467); catalogued as COSV58304759; called by muse, mutect2, varscan2
- PHACTR3 | c.1356A>C p.E452D | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV63028624; called by muse, mutect2, varscan2
- PHOSPHO1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV56800342; called by muse, mutect2, varscan2
- PIK3C2A | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV56403304; called by muse, mutect2, varscan2
- PJA1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760451597, COSV64053231; called by muse, mutect2, varscan2
- PPP1R9A | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs765903491, COSV56895115; called by muse, mutect2, varscan2
- PRAMEF14 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100577261; called by muse, mutect2, varscan2
- PRKG1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs1440365856, COSV100911761; called by muse, mutect2, varscan2
- RAG1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs773742414, COSV55025453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBMXL2 | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60980370; called by muse, mutect2, varscan2
- RBP2 | c.333T>G p.I111M | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as COSV51673870; called by muse, mutect2, varscan2
- RELN | c.7001A>C p.K2334T | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.796); catalogued as COSV59005517; called by muse, mutect2, varscan2
- RGS20 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.043); catalogued as rs1435871455, COSV52017447; called by muse, mutect2, varscan2
- RHPN2 | c.1385A>C p.D462A | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54279540; called by muse, mutect2, varscan2
- RIMS2 | c.2373A>C p.E791D (on ENST00000666250 / NM_001348490.2; = p.E599D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51686303; called by muse, mutect2
- RMDN3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758632389, COSV53024237; called by muse, mutect2, varscan2
- RNF182 | c.266T>G p.V89G | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV70369334; called by muse, mutect2, varscan2
- RNF34 | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196981863, COSV63442220; called by muse, mutect2, varscan2
- RPRM | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1196453867, COSV57988436; called by muse, mutect2, varscan2
- RXFP3 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs943555578, COSV57505946; called by muse, mutect2, varscan2
- RYR1 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.349); catalogued as rs1202941571, COSV62098958; called by muse, mutect2, varscan2
- SCAF4 | c.3152G>C p.R1051T | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV54256258; called by muse, varscan2
- SCAF4 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54587684, COSV99740707; called by muse, mutect2, varscan2
- SCN10A | c.3767G>A p.R1256Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1280130231, COSV71861698; called by muse, mutect2, varscan2
- SCN11A | c.4895A>C p.K1632T | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56567145; called by muse, mutect2, varscan2
- SENP2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs775072409, COSV56194742; called by muse, mutect2, varscan2
- SH3BP5L | c.656T>G p.I219S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63539298; called by muse, mutect2, varscan2
- SIGLEC10 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763916091, COSV59482366; called by muse, mutect2, varscan2
- SLC16A2 | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV52085169; called by muse, mutect2
- SLC8A1 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.47); PolyPhen benign (0.293); catalogued as rs760942212, COSV60479502, COSV60482244; called by muse, mutect2, varscan2
- SLITRK5 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs1250039111, COSV61520515, COSV61523238; called by muse, mutect2, varscan2
- SPTA1 | c.3287A>G p.E1096G | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV63754143; called by muse, mutect2, varscan2
- SRCAP | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 133/172 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV52673518; called by muse, mutect2, varscan2
- TAGAP | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57852121; called by muse, mutect2, varscan2
- TDRP | c.265T>G p.W89G | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV60705988; called by muse, mutect2, varscan2
- TNC | c.3724T>G p.F1242V | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as COSV60785477; called by muse, mutect2, varscan2
- TOPORS | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV62116746; called by muse, mutect2
- TRAPPC9 | c.1018G>C p.A340P | Missense Mutation (SNP) | VAF 96/116 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66900740; called by muse, mutect2, varscan2
- TRIM48 | c.542T>G p.I181S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV70161684; called by muse, mutect2, varscan2
- TRPA1 | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 125/251 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV51562698; called by muse, mutect2, varscan2
- TRPC5 | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV53291803; called by muse, mutect2, varscan2
- TRPM3 | c.2155G>A p.D719N (on ENST00000357533 / NM_001366142.2; = p.D562N on NM_020952.6) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.086); catalogued as COSV62587048; called by muse, mutect2, varscan2
- TSPOAP1 | c.3346C>A p.L1116I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV52109756; called by muse, mutect2, varscan2
- TTN | c.95770G>A p.A31924T (on ENST00000591111; = p.A24500T on NM_003319.4) | Missense Mutation (SNP) | VAF 38/99 reads (38%) | PolyPhen benign (0.271); catalogued as rs373484505, COSV60101350; called by muse, mutect2, varscan2
- TTN | c.60427G>A p.D20143N (on ENST00000591111; = p.D12719N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | PolyPhen probably damaging (0.998); catalogued as COSV60101379; called by muse, mutect2, varscan2
- TTN | c.42430G>A p.D14144N (on ENST00000591111; = p.D6720N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | PolyPhen probably damaging (0.998); catalogued as rs755971270, COSV60101417; called by muse, mutect2, varscan2
- TTN | c.22323T>G p.S7441R (on ENST00000591111; = p.S6514R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | PolyPhen benign (0.247); catalogued as rs1402117670, COSV60101450; called by muse, mutect2, varscan2
- TTN | c.3312A>T p.Q1104H (on ENST00000591111; = p.Q1058H on NM_003319.4) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | PolyPhen possibly damaging (0.808); catalogued as COSV100592269, COSV59896378, COSV60101462; called by muse, mutect2, varscan2
- UBXN7 | c.228A>C p.E76D | Missense Mutation (SNP) | VAF 123/198 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV56355778; called by muse, mutect2, varscan2
- VEGFB | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs998276317, COSV58536917; called by muse, mutect2, varscan2
- VRTN | c.1231C>A p.H411N | Missense Mutation (SNP) | VAF 80/95 reads (84%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV56441326; called by muse, mutect2, varscan2
- ZBBX | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56790846; called by muse, mutect2, varscan2
- ZC3H3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1169928659, COSV52790402; called by muse, mutect2, varscan2
- ZDBF2 | c.1829T>C p.V610A | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as rs776137882, COSV65626655; called by muse, mutect2, varscan2
- ZIC2 | c.1172A>T p.K391M | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66255019; called by muse, mutect2, varscan2
- ZNF135 | c.661A>G p.K221E (on ENST00000313434 / NM_001289401.2; = p.K233E on NM_003436.4) | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV57882735; called by muse, mutect2, varscan2
- ZNF438 | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV59195680; called by muse, mutect2, varscan2
- ZNF48 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as rs1258488644, COSV60783381; called by muse, mutect2
- ZNF497 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.9); catalogued as COSV99568192; called by muse, mutect2, varscan2
- ZNF540 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57109548; called by muse, mutect2, varscan2
- ZNF70 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 66/94 reads (70%) | SIFT tolerated (0.51); PolyPhen benign (0.258); catalogued as rs143352353; called by muse, mutect2, varscan2
- ZNF770 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV62544378; called by muse, mutect2, varscan2
- ZZEF1 | c.2039A>C p.K680T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67557861; called by muse, mutect2, varscan2
- FAT2 | c.2007_2008del p.C670* | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- KDM4D | c.278dup p.K94Efs*15 | Frame Shift Ins (INS) | VAF 28/86 reads (33%) | called by mutect2, varscan2
- OR52D1 | c.26del p.N9Tfs*9 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1163A>T p.K388I | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ABCA12 | c.7173T>C p.S2391= (on ENST00000272895 / NM_173076.3; = p.S2073= on NM_015657.3) | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV55960983; called by muse, mutect2, varscan2
- BCAM | c.1485A>G p.P495= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV54302638; called by muse, mutect2, varscan2
- CABP4 | c.189C>T p.G63= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs984841482, COSV56886699; called by muse, mutect2, varscan2
- CATSPERG | c.1959A>G p.R653= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV53049178; called by muse, mutect2, varscan2
- CNTNAP5 | c.1818C>T p.I606= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs374813240; called by muse, mutect2, varscan2
- CORO6 | c.285C>T p.N95= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as rs758461627, COSV61471032; called by muse, mutect2, varscan2
- CSMD2 | c.6951C>T p.I2317= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV53897759, COSV53911750; called by muse, mutect2, varscan2
- DDX11 | c.2019A>G p.E673= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as COSV52504932; called by muse, mutect2, varscan2
- DNAH10 | c.11640T>G p.G3880= (on ENST00000409039; = p.G3819= on NM_207437.3) | Silent (SNP) | VAF 44/55 reads (80%) | catalogued as COSV68994706; called by muse, mutect2, varscan2
- EIF3J | c.405T>G p.T135= | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as COSV56008906; called by muse, mutect2, varscan2
- EP400 | c.1269G>A p.L423= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs753728916, COSV57773904; called by muse, mutect2, varscan2
- ERG | c.1452T>G p.T484= (on ENST00000398919 / NM_001243428.1; = p.T460= on NM_004449.4) | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV55732875; called by muse, mutect2, varscan2
- EXOC6 | c.2205T>G p.T735= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as COSV53325254; called by muse, mutect2, varscan2
- FAM177A1 | c.321T>G p.A107= (on ENST00000382406 / NM_001289022.2; = p.A130= on NM_173607.5) | Silent (SNP) | VAF 28/288 reads (10%) | catalogued as COSV55241012; called by muse, mutect2
- FANCI | c.1752C>T p.C584= | Silent (SNP) | VAF 96/118 reads (81%) | catalogued as COSV55527944; called by muse, mutect2, varscan2
- FGFR1 | c.1464C>T p.C488= (on ENST00000447712 / NM_023110.3; = p.C486= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV58334208; called by muse, mutect2, varscan2
- GRIK2 | c.1419C>A p.I473= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs763110619, COSV59717550, COSV59740137; called by muse, mutect2, varscan2
- H2AC14 | c.126G>A p.E42= | Silent (SNP) | VAF 3/62 reads (5%) | catalogued as COSV100297687; called by muse, mutect2
- HOXD12 | c.249C>T p.L83= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV66832630; called by muse, mutect2
- ISG15 | c.363G>A p.L121= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs934874303, COSV65106557; called by muse, mutect2, varscan2
- KCNH5 | c.12C>A p.G4= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV59761871; called by muse, mutect2, varscan2
- KRT33B | c.630C>T p.N210= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs778778969, COSV52441089; called by muse, mutect2, varscan2
- LECT2 | c.213T>C p.T71= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV50847196; called by muse, mutect2, varscan2
- LRAT | c.72C>T p.L24= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV60477175; called by muse, mutect2, varscan2
- LRP1 | c.8505C>T p.F2835= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs745849478, COSV54513311; called by muse, mutect2, varscan2
- MOXD1 | c.1635A>G p.P545= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as rs768612171, COSV60944973; called by muse, mutect2, varscan2
- NCOA6 | c.1422G>A p.P474= | Silent (SNP) | VAF 96/210 reads (46%) | catalogued as rs1322647185, COSV62861211, COSV62865532; called by muse, mutect2, varscan2
- OR1J1 | c.651T>C p.S217= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV52238665; called by muse, mutect2, varscan2
- OR2Z1 | c.21G>A p.S7= | Silent (SNP) | VAF 49/61 reads (80%) | catalogued as rs781936306, COSV60691925; called by muse, mutect2, varscan2
- PAMR1 | c.2007G>A p.A669= (on ENST00000619888 / NM_001001991.3; = p.A686= on NM_015430.4) | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs370631386; called by muse, mutect2, varscan2
- POM121 | c.3642T>G p.V1214= (on ENST00000434423; = p.V949= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV57516704; called by muse, mutect2, varscan2
- RASL11A | c.378C>T p.P126= | Silent (SNP) | VAF 46/63 reads (73%) | catalogued as COSV54080309; called by muse, mutect2, varscan2
- RBBP7 | c.414C>T p.I138= | Silent (SNP) | VAF 62/68 reads (91%) | catalogued as COSV66300906, COSV66301466; called by muse, mutect2, varscan2
- RIC1 | c.477T>G p.T159= | Silent (SNP) | VAF 773/817 reads (95%) | catalogued as COSV52610114; called by muse, mutect2, varscan2
- RNF40 | c.1311G>A p.L437= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1257944098, COSV100221907; called by muse, mutect2
- SCAF4 | c.3213G>A p.E1071= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV54256249; called by muse, varscan2
- SCN5A | c.1014C>T p.G338= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV61117933, COSV61126080; called by muse, mutect2, varscan2
- SIX6 | c.75C>T p.G25= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV59802373; called by muse, mutect2, varscan2
- SPTA1 | c.387G>A p.T129= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs756658385, COSV63754147; called by muse, mutect2, varscan2
- ST8SIA5 | c.798C>T p.D266= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as COSV59330957, COSV59332250; called by muse, mutect2, varscan2
- SYNE1 | c.24786T>C p.A8262= (on ENST00000367255 / NM_182961.4; = p.A8191= on NM_033071.3) | Silent (SNP) | VAF 44/70 reads (63%) | catalogued as COSV54996894; called by muse, mutect2, varscan2
- SYNE1 | c.11829C>T p.G3943= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs146547806, COSV54996937; called by muse, mutect2, varscan2
- TNS4 | c.1914G>A p.V638= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV54185271; called by muse, mutect2, varscan2
- UPK2 | c.495C>T p.V165= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs776578281, COSV50629061; called by muse, mutect2, varscan2
- USP6NL | c.1653C>T p.Y551= | Silent (SNP) | VAF 61/170 reads (36%) | catalogued as rs768540914, COSV53211946; called by muse, mutect2, varscan2
- WNK3 | c.4053A>C p.T1351= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as COSV63614346; called by muse, mutect2, varscan2
- ZNF667 | c.1132A>C p.R378= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV52635050; called by muse, mutect2, varscan2
- ZNF695 | c.1539T>C p.T513= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs924054570, COSV60586153; called by muse, mutect2, varscan2
- BIRC8 | n.1344A>C | RNA (SNP) | VAF 54/178 reads (30%) | catalogued as COSV70346980; called by muse, mutect2, varscan2
- DCHS2 | n.3666A>G | RNA (SNP) | VAF 28/35 reads (80%) | catalogued as COSV61772799; called by muse, mutect2, varscan2
- KLK8 | c.71-28C>T | Intron (SNP) | VAF 40/101 reads (40%) | catalogued as rs764327775, COSV99143865; called by muse, mutect2, varscan2
- LINC01565 | n.1290G>T | RNA (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+4985G>A | Intron (SNP) | VAF 18/198 reads (9%) | catalogued as rs140933134, COSV99961876; called by muse, mutect2
- MFSD11 | chr17:76736508 G>A | 5'Flank (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100333498; called by muse, mutect2, varscan2
- PNLIPRP1 | c.331-411C>T | Intron (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100724267; called by muse, mutect2
- SLIT3 | c.1459+4544T>G | Intron (SNP) | VAF 8/9 reads (89%) | catalogued as COSV100265543; called by muse, mutect2, varscan2
- SNORD115-43 | n.24T>C | RNA (SNP) | VAF 243/305 reads (80%) | catalogued as rs749444256; called by muse, mutect2, varscan2
- TRAC | c.*430G>C | 3'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
